Somatic mutation profile of tumor specimen MMRF_1242_4_BM_CD138pos (aliquot MMRF_1242_4_BM_CD138pos_T1_KBS5U_L05371) from MMRF case MMRF_1242, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,392 days).
Specimen MMRF_1242_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f126509e-39ea-46e3-a45d-88c16aa43b9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1242_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1242_1_PB_Whole_C1_KBS5U_L05353; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6c4dd4-202d-497c-9760-d6f0b81a23ce

The open-access MAF lists 32 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 8, Missense Mutation 7, Silent 7, Intron 4, Nonsense Mutation 4, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BHLHE41 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.111); catalogued as rs1298614273; called by muse, mutect2
- CPA1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50569686; called by muse, mutect2
- INO80 | c.3817G>C p.E1273Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62738340; called by muse, mutect2
- PEX11B | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as rs781924210, COSV57161932; called by muse, mutect2
- SCAMP3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as rs1355670993; called by muse, mutect2
- ATCAY | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2
- CDC73 | c.69C>G p.D23E | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- FAM160A2 | c.2038G>T p.E680* (on ENST00000449352 / NM_001098794.2; = p.E694* on NM_032127.4) | Nonsense Mutation (SNP) | VAF 10/237 reads (4%) | called by muse, mutect2
- FUT2 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.401); called by muse, mutect2
- GNG5 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2
- SLIT2 | c.2752A>T p.K918* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- DISP2 | c.1863C>T p.F621= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- NUP214 | c.3348G>A p.L1116= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- OBSCN | c.21954C>G p.L7318= | Silent (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- PGAP1 | c.24C>T p.L8= | Silent (SNP) | VAF 11/175 reads (6%) | called by muse, mutect2
- PHKA1 | c.1386G>A p.V462= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV59808326; called by muse, mutect2
- SLC25A20 | c.102C>T p.V34= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SLC9C2 | c.2965C>T p.L989= | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- CEP170 | c.3677-278C>T | Intron (SNP) | VAF 18/240 reads (8%) | catalogued as rs3015131; called by muse, mutect2
- DCAF10 | c.*971G>C | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- EIF3F | chr11:7997745 G>A | 3'Flank (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ELL2 | c.1761+94G>C | Intron (SNP) | VAF 5/106 reads (5%) | catalogued as rs1463389226; called by muse, mutect2
- GABRA4 | c.*8986C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- POU3F3 | c.*101C>T | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- PRDM15 | c.2591-139C>T | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- PTBP2 | c.1069-197C>T | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- SLC35F2 | c.*1060C>T | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SOX13 | c.*405C>T | 3'UTR (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- SP2 | c.*845C>G | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- SVIP | c.*711C>G | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- VAMP4 | c.*3511C>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
